Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4HD, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4HD-01A (Primary Tumor).

Stomach, Subtotal gastrectomy

- 1) Specimen size: Lesser curvature - 15.5 cm, Greater curvature - 28 cm, Fresh, opened
- 2) Tumor location: a) Lower third, b) Greater curvature
- 3) Gross type: Borrmann type 2
- 4) Resection margin: Free from carcinoma, Safety margin: Proximal 11 cm, Distal 1.6 cm
- 5) Tumor size: 4.5x3 cm
- 6) Estimated depth of invasion: into the subserosal layer

Pathologic Findings

- 1) T: 20-23, Mass
- 1) Histologic Type: Tubular adenocarcinoma, intestinal type
- 2) Histologic Grade: G2 (Moderately differentiated)
- 3) Pathologic Staging (pTNM): pT3 (Invades subserosa) (AJCC 7th), pN2 (No. examined: 58, No. involved: 3), pM0
- 4) Margins: Proximal Margin (#18): Free from tumor cell invasion, Distal Margin (#19): Free from tumor cell invasion
- 5) Lymphovascular invasion: Present, Lymphatics
- 6) Perineural invasion: Absent
- 7) Pre-existing Adenoma: None
- 8) Additional Pathologic Findings (Ulceration, perforation, etc.): None

5-6: LN 4a (2/12), 9: LN 6 (1/4) Involved by tumor cells

1: LN 1 (Fibroadipose tissue), 2-4: LN 3 (0/12), 7: LN 4sb (0/1), 8: LN 5 (0/7), 10: LN 7 (0/7), 11: LN 8a (0/2), 12-13: LN 9 (0/11), 14: LN 10 (0/1), 15: LN 12a (Fibroadipose tissue): Free from tumor cell invasion

16: Normal: Chronic gastritis

Immunohistochemical stains

CD34 (-), D2-40 (+), C-erbB2 (3+)

ICD-O-3

adenocarcinoma, tubular, 8211/3

Clin Site: Stomach, entrium C16.3

Path: Stomach, greater curvature C16.6

STOMACH23 block.txt

TUBULAR ADENOCARCINOMA, INTESTINAL TYPE, MODERATELY DIFFERENTIATED

INVADES SUBSEROA (#17, 20-23)

hw
9/27/12

Case/Collection		

Source: NCI Genomic Data Commons file 52999f94-8456-4c9b-9e56-cd168502a07b (TCGA-HU-A4HD.AC667C8E-A2B2-4229-9B7A-3B6C20633437.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).